Somatic mutation profile of tumor specimen TCGA-DD-A73E-01A (aliquot TCGA-DD-A73E-01A-12D-A32G-10) from TCGA case TCGA-DD-A73E, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 66.7 years (24,377 days).
Specimen TCGA-DD-A73E-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 475c718c-37f6-442a-a0af-1611461e2c3c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A73E-10A (Blood Derived Normal), aliquot TCGA-DD-A73E-10A-01D-A32G-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c2becdef-fe49-4967-82f6-cb521c0e300b

The open-access MAF lists 126 somatic variants for this specimen: 85 protein-altering or splice-affecting, 38 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, Silent 38, Frame Shift Del 4, Splice Site 3, Nonsense Mutation 2, Intron 1, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1E | c.2101A>G p.I701V | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.956); catalogued as rs1558308998, COSV62381966; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.95A>T p.D32V | Missense Mutation (SNP) | VAF 78/211 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs121913396, COSV62688001, COSV62688037, COSV62688249; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AHCTF1 | c.3887G>T p.C1296F (on ENST00000366508; = p.C1270F on NM_015446.5) | Missense Mutation (SNP) | VAF 111/392 reads (28%) | SIFT tolerated (0.72); PolyPhen benign (0.015); catalogued as rs1296469036, COSV58245716; called by muse, mutect2, varscan2
- AP2B1 | c.451A>G p.I151V | Missense Mutation (SNP) | VAF 103/170 reads (61%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV51996944; called by muse, mutect2, varscan2
- ASH1L | c.4547G>C p.R1516P | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); catalogued as COSV64205389; called by muse, mutect2, varscan2
- ASXL3 | c.2387A>T p.N796I | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.143); catalogued as COSV52457036; called by muse, mutect2, varscan2
- BRINP1 | c.382C>G p.H128D | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56291878; called by muse, mutect2, varscan2
- CDH23 | c.2237T>G p.V746G | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV54924153; called by muse, mutect2, varscan2
- CLCA4 | c.1600G>A p.D534N | Missense Mutation (SNP) | VAF 92/230 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV55365990; called by muse, mutect2, varscan2
- CNTNAP2 | c.302A>T p.Q101L | Missense Mutation (SNP) | VAF 103/170 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62144719; called by muse, mutect2, varscan2
- COL9A2 | c.1242del p.G415Efs*116 | Frame Shift Del (DEL) | VAF 31/77 reads (40%) | catalogued as rs756694568; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- CPEB4 | c.7G>T p.D3Y | Missense Mutation (SNP) | VAF 85/216 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV54169473; called by muse, mutect2, varscan2
- CRB1 | c.3806A>G p.Y1269C | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.188); catalogued as rs1275856765, COSV66328613; called by muse, mutect2, varscan2
- CROCC | c.5G>A p.S2N | Missense Mutation (SNP) | VAF 41/208 reads (20%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.001); catalogued as COSV65009931; called by muse, mutect2, varscan2
- CSNK1E | c.1160A>G p.N387S | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.214); catalogued as COSV63290354; called by muse, mutect2, varscan2
- DYNC2H1 | c.11336T>G p.L3779W | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62085961; called by muse, mutect2, varscan2
- F10 | c.310G>T p.G104C | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65020746; called by muse, mutect2, varscan2
- FAT2 | c.1883T>C p.L628P | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV55813073; called by muse, mutect2, varscan2
- FBN2 | c.6336G>T p.K2112N | Missense Mutation (SNP) | VAF 58/147 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.801); catalogued as COSV52492554; called by muse, mutect2, varscan2
- FCN1 | c.970C>T p.R324W | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765314208, COSV65661949; called by muse, mutect2, varscan2
- FHOD3 | c.1948A>T p.R650W (on ENST00000359247 / NM_001281739.3; = p.R667W on NM_025135.5) | Missense Mutation (SNP) | VAF 62/95 reads (65%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV57164163; called by muse, mutect2, varscan2
- FMO1 | c.931G>T p.V311F | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV61444623; called by muse, mutect2, varscan2
- FSTL5 | c.1946C>T p.P649L | Missense Mutation (SNP) | VAF 39/174 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60181084; called by muse, mutect2, varscan2
- GABRB1 | c.1342T>C p.S448P | Missense Mutation (SNP) | VAF 59/135 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.21); catalogued as COSV54970441; called by muse, mutect2, varscan2
- GLRA2 | c.69G>C p.R23S | Missense Mutation (SNP) | VAF 161/183 reads (88%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.005); catalogued as COSV54335943; called by muse, mutect2, varscan2
- GLRB | c.230-1G>C p.X77_splice | Splice Site (SNP) | VAF 136/567 reads (24%) | catalogued as COSV52412807; called by muse, mutect2, varscan2
- GPR83 | c.700C>A p.L234I | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.843); catalogued as COSV99703611; called by muse, varscan2
- HNF4A | c.337C>T p.R113C | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CX1310373, COSV57379530, COSV57387659; called by muse, mutect2, varscan2
- HOMER1 | c.403G>T p.D135Y | Missense Mutation (SNP) | VAF 54/107 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.427); catalogued as COSV56523606; called by muse, mutect2, varscan2
- HYDIN | c.14935G>T p.G4979C | Missense Mutation (SNP) | VAF 58/114 reads (51%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV66637124; called by muse, mutect2, varscan2
- IARS2 | c.1063T>A p.S355T | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0.012); catalogued as COSV56957503; called by muse, mutect2, varscan2
- IFNA4 | c.70T>C p.C24R | Missense Mutation (SNP) | VAF 149/346 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV70179674; called by muse, mutect2, varscan2
- IRX4 | c.791A>G p.D264G | Missense Mutation (SNP) | VAF 68/167 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.3); catalogued as COSV51470680; called by muse, mutect2, varscan2
- ITIH4 | c.545A>G p.Q182R | Missense Mutation (SNP) | VAF 31/51 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV56571284; called by muse, mutect2, varscan2
- KCNA4 | c.1957G>T p.V653L | Missense Mutation (SNP) | VAF 48/115 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as COSV60250649; called by muse, mutect2, varscan2
- KCNK6 | c.917C>T p.T306I | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.099); catalogued as rs371433357; called by muse, mutect2, varscan2
- KCTD20 | c.427C>G p.L143V | Missense Mutation (SNP) | VAF 71/218 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54802066; called by muse, mutect2, varscan2
- KMT2B | c.5334C>A p.C1778* | Nonsense Mutation (SNP) | VAF 30/80 reads (38%) | catalogued as COSV55856973; called by muse, mutect2, varscan2
- KRT33B | c.896C>T p.T299M | Missense Mutation (SNP) | VAF 69/124 reads (56%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.473); catalogued as rs199838257, COSV52440114; called by muse, mutect2, varscan2
- LRP1B | c.3002G>T p.G1001V | Missense Mutation (SNP) | VAF 57/163 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV67185660; called by muse, mutect2, varscan2
- LRP4 | c.1720G>A p.G574S | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV66133951; called by muse, mutect2, varscan2
- LSR | c.229C>T p.L77F | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.614); catalogued as rs1167044758, COSV61554652; called by muse, mutect2, varscan2
- MAK | c.1317-1G>T p.X439_splice | Splice Site (SNP) | VAF 63/182 reads (35%) | catalogued as COSV57564050; called by muse, mutect2, varscan2
- MOB3B | c.631A>G p.T211A | Missense Mutation (SNP) | VAF 52/107 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV51774940; called by muse, mutect2, varscan2
- MYH13 | c.3184G>A p.D1062N | Missense Mutation (SNP) | VAF 64/76 reads (84%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52820592; called by muse, mutect2, varscan2
- NADSYN1 | c.1739A>C p.D580A | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.014); catalogued as COSV59810039; called by muse, mutect2, varscan2
- OGFOD2 | c.251T>G p.L84R (on ENST00000228922 / NM_001304833.1; = p.L24R on NM_024623.3) | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV57440595; called by muse, mutect2, varscan2
- OR10Q1 | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs960762436, COSV57469692; called by muse, mutect2, varscan2
- OR2G2 | c.556G>A p.V186M | Missense Mutation (SNP) | VAF 85/265 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV60739338; called by muse, mutect2, varscan2
- OR52N1 | c.329C>T p.T110I | Missense Mutation (SNP) | VAF 37/68 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as COSV57692908; called by muse, mutect2
- OTOP2 | c.306G>T p.W102C | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV58880544; called by muse, mutect2, varscan2
- PCDHA6 | c.704T>C p.V235A | Missense Mutation (SNP) | VAF 81/163 reads (50%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.007); catalogued as COSV65349274; called by muse, mutect2, varscan2
- PCDHAC2 | c.1513A>G p.T505A | Missense Mutation (SNP) | VAF 64/150 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as COSV53836637; called by muse, mutect2, varscan2
- PHB2 | c.640G>C p.V214L | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54640894; called by muse, mutect2, varscan2
- PLA2G2F | c.100C>T p.P34S | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs1233644467, COSV64279749; called by muse, mutect2, varscan2
- PPT2 | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT tolerated (0.66); PolyPhen benign (0.346); catalogued as COSV52997487; called by muse, mutect2, varscan2
- RANBP17 | c.1843T>G p.F615V | Missense Mutation (SNP) | VAF 68/155 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as COSV66644260; called by muse, mutect2, varscan2
- RASAL1 | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 57/123 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as rs150792397; called by muse, mutect2, varscan2
- RASGEF1A | c.1012G>T p.A338S | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.45); catalogued as rs1441582766, COSV65666637, COSV65666663; called by muse, mutect2, varscan2
- SALL4 | c.1705C>T p.L569F | Missense Mutation (SNP) | VAF 57/118 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.523); catalogued as COSV53849766; called by muse, mutect2, varscan2
- SCN2A | c.5188G>T p.D1730Y | Missense Mutation (SNP) | VAF 55/304 reads (18%) | SIFT tolerated (0.42); PolyPhen probably damaging (1); catalogued as COSV51832057; called by muse, mutect2, varscan2
- SLC24A2 | c.776A>G p.N259S | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.759); catalogued as COSV53857275; called by muse, mutect2, varscan2
- SLC5A1 | c.1229A>G p.Y410C | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56683358; called by muse, mutect2, varscan2
- SLCO3A1 | c.82A>G p.K28E | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59224828; called by muse, mutect2, varscan2
- SMOC2 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 52/66 reads (79%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs765267119, COSV62433766; called by muse, mutect2, varscan2
- SPAG6 | c.743T>C p.V248A | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.521); catalogued as COSV57617908; called by muse, mutect2, varscan2
- TARS1 | c.294G>A p.W98* | Nonsense Mutation (SNP) | VAF 58/131 reads (44%) | catalogued as COSV54307448; called by muse, mutect2, varscan2
- TBX2 | c.1289G>A p.R430Q | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.69); catalogued as COSV53597559; called by muse, mutect2, varscan2
- TDRD6 | c.4576A>G p.T1526A | Missense Mutation (SNP) | VAF 85/273 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); catalogued as COSV60173842; called by muse, mutect2, varscan2
- THBS3 | c.808+1G>T p.X270_splice | Splice Site (SNP) | VAF 57/132 reads (43%) | catalogued as COSV64248437; called by muse, mutect2, varscan2
- THSD7B | c.4289G>A p.G1430D (on ENST00000272643; = p.G1428D on NM_001316349.2) | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55653381; called by muse, mutect2, varscan2
- TPO | c.1346C>T p.T449I | Missense Mutation (SNP) | VAF 79/228 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV61094392; called by muse, mutect2, varscan2
- TRIM59 | c.672A>T p.R224S | Missense Mutation (SNP) | VAF 62/199 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as COSV59086421; called by muse, mutect2, varscan2
- TTN | c.19422G>C p.E6474D (on ENST00000591111; = p.E5547D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 120/220 reads (55%) | PolyPhen benign (0.003); catalogued as COSV59883961; called by muse, mutect2, varscan2
- TYSND1 | c.1495A>T p.S499C | Missense Mutation (SNP) | VAF 71/158 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54642271; called by muse, mutect2, varscan2
- USP19 | c.1682C>T p.T561I | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60044867; called by muse, mutect2, varscan2
- USP53 | c.941G>T p.W314L | Missense Mutation (SNP) | VAF 52/107 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56792214; called by muse, mutect2, varscan2
- WDR7 | c.796G>A p.V266I | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs759312541, COSV54348029; called by muse, mutect2, varscan2
- ZC3H18 | c.2650G>T p.A884S | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.79); catalogued as COSV56322515; called by muse, mutect2, varscan2
- ZFHX3 | c.8545G>C p.D2849H | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51708330; called by muse, mutect2, varscan2
- ZNFX1 | c.4270T>C p.Y1424H | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs970811013, COSV65594127; called by muse, mutect2, varscan2
- ZRANB3 | c.2267G>A p.S756N | Missense Mutation (SNP) | VAF 82/274 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV51493672; called by muse, mutect2, varscan2
- IBTK | c.2705del p.N902Ifs*14 | Frame Shift Del (DEL) | VAF 95/147 reads (65%) | called by mutect2, pindel, varscan2
- OSER1 | c.323_330del p.H108Pfs*3 | Frame Shift Del (DEL) | VAF 48/115 reads (42%) | called by mutect2, pindel, varscan2
- PCDHB3 | c.1735del p.A579Rfs*8 | Frame Shift Del (DEL) | VAF 8/49 reads (16%) | called by pindel, varscan2
- ADGRE3 | c.1752C>A p.T584= | Silent (SNP) | VAF 33/73 reads (45%) | catalogued as COSV53728303; called by muse, mutect2, varscan2
- ADPRH | c.969G>A p.V323= | Silent (SNP) | VAF 56/107 reads (52%) | catalogued as COSV63694433; called by muse, mutect2, varscan2
- AGT | c.174T>C p.N58= | Silent (SNP) | VAF 41/153 reads (27%) | catalogued as COSV64183692; called by muse, mutect2, varscan2
- APH1B | c.211C>T p.L71= | Silent (SNP) | VAF 14/154 reads (9%) | catalogued as COSV56013696, COSV56014386; called by muse, mutect2
- C1QB | c.477C>T p.T159= | Silent (SNP) | VAF 71/153 reads (46%) | catalogued as COSV59244987; called by muse, mutect2, varscan2
- C1orf87 | c.294C>T p.N98= | Silent (SNP) | VAF 100/225 reads (44%) | catalogued as rs760547532, COSV64596013; called by muse, mutect2, varscan2
- C4orf51 | c.345A>G p.S115= | Silent (SNP) | VAF 131/478 reads (27%) | catalogued as COSV71263722; called by muse, mutect2, varscan2
- CCKAR | c.51C>T p.P17= | Silent (SNP) | VAF 40/95 reads (42%) | catalogued as COSV55159692; called by muse, mutect2, varscan2
- CCT2 | c.795A>G p.A265= | Silent (SNP) | VAF 25/79 reads (32%) | catalogued as COSV54739099; called by muse, mutect2, varscan2
- CDH6 | c.2257C>T p.L753= | Silent (SNP) | VAF 68/153 reads (44%) | catalogued as COSV54063969; called by muse, mutect2, varscan2
- CNTN5 | c.186G>T p.L62= | Silent (SNP) | VAF 40/200 reads (20%) | catalogued as COSV54280181; called by muse, varscan2
- CSMD3 | c.3921A>T p.L1307= (on ENST00000297405 / NM_001363185.1; = p.L1203= on NM_052900.3) | Silent (SNP) | VAF 18/81 reads (22%) | catalogued as COSV52101312; called by muse, mutect2, varscan2
- CWF19L2 | c.1206T>C p.C402= | Silent (SNP) | VAF 100/198 reads (51%) | catalogued as COSV56508436; called by muse, mutect2, varscan2
- DHCR7 | c.1380G>A p.E460= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as COSV62794401; called by muse, mutect2, varscan2
- DNAI3 | c.1239T>A p.I413= | Silent (SNP) | VAF 51/144 reads (35%) | catalogued as COSV54000516; called by muse, mutect2, varscan2
- DOK1 | c.492C>T p.A164= | Silent (SNP) | VAF 34/105 reads (32%) | catalogued as COSV51206121; called by muse, mutect2, varscan2
- FLNC | c.4272G>C p.G1424= | Silent (SNP) | VAF 80/112 reads (71%) | catalogued as rs759650097, COSV100367544, COSV57950090; called by muse, mutect2, varscan2
- HDAC3 | c.567G>A p.T189= | Silent (SNP) | VAF 49/109 reads (45%) | catalogued as rs770968916, COSV100539450, COSV59495017; called by muse, mutect2, varscan2
- ILVBL | c.594G>T p.S198= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV54617833; called by muse, mutect2, varscan2
- JAG1 | c.48C>A p.L16= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as rs901489977, COSV54753355; called by muse, mutect2, varscan2
- LDHD | c.1140G>T p.T380= | Silent (SNP) | VAF 29/57 reads (51%) | catalogued as rs916656057, COSV55580022; called by muse, mutect2, varscan2
- LYG2 | c.321T>C p.H107= | Silent (SNP) | VAF 36/67 reads (54%) | catalogued as rs773368455, COSV60715223; called by muse, mutect2, varscan2
- MNAT1 | c.354C>T p.T118= | Silent (SNP) | VAF 215/442 reads (49%) | catalogued as COSV54186607; called by muse, mutect2, varscan2
- MRC2 | c.3561G>A p.L1187= | Silent (SNP) | VAF 16/27 reads (59%) | catalogued as COSV57636593; called by muse, mutect2, varscan2
- MYH3 | c.954G>A p.E318= | Silent (SNP) | VAF 10/185 reads (5%) | catalogued as COSV56860813; called by muse, mutect2
- MYOD1 | c.540G>T p.A180= | Silent (SNP) | VAF 3/43 reads (7%) | catalogued as rs1288742781; called by muse, mutect2
- NR3C1 | c.1743A>T p.I581= | Silent (SNP) | VAF 63/123 reads (51%) | catalogued as COSV51539836; called by muse, mutect2, varscan2
- OBSCN | c.7470C>T p.C2490= | Silent (SNP) | VAF 47/144 reads (33%) | catalogued as rs553927346, COSV52739043; called by muse, mutect2, varscan2
- PCDHGA8 | c.1152T>C p.C384= | Silent (SNP) | VAF 54/121 reads (45%) | catalogued as COSV53897864; called by muse, mutect2, varscan2
- PENK | c.803A>G p.*268= | Silent (SNP) | VAF 38/44 reads (86%) | catalogued as COSV59240053; called by mutect2, varscan2
- PKIB | c.144A>G p.K48= | Silent (SNP) | VAF 8/11 reads (73%) | catalogued as COSV57794057; called by muse, mutect2, varscan2
- SARM1 | c.2139C>T p.T713= | Silent (SNP) | VAF 53/94 reads (56%) | catalogued as COSV50229225; called by muse, mutect2, varscan2
- SCN11A | c.3321A>G p.L1107= | Silent (SNP) | VAF 37/102 reads (36%) | catalogued as COSV56565585; called by muse, mutect2, varscan2
- SCN1A | c.2112A>G p.L704= (on ENST00000303395 / NM_001202435.3; = p.L693= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 59/142 reads (42%) | catalogued as COSV57659590; called by muse, mutect2, varscan2
- SLC25A16 | c.942T>A p.S314= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV56263856; called by muse, mutect2, varscan2
- TDRD5 | c.1467G>C p.R489= | Silent (SNP) | VAF 34/85 reads (40%) | catalogued as COSV54238796, COSV54251024; called by muse, mutect2, varscan2
- TRMT1 | c.1149G>A p.E383= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as rs754696958, COSV55564542; called by muse, mutect2, varscan2
- ZNF320 | c.1095T>G p.A365= | Silent (SNP) | VAF 38/91 reads (42%) | catalogued as COSV67087541; called by muse, mutect2, varscan2
- ELMOD1 | c.-86+445C>T | Intron (SNP) | VAF 39/82 reads (48%) | catalogued as COSV56190621; called by muse, mutect2, varscan2
- MATK | c.-2C>T | 5'UTR (SNP) | VAF 23/44 reads (52%) | catalogued as rs772163315, COSV100035915; called by muse, mutect2, varscan2
- MIR891B | n.21C>A | RNA (SNP) | VAF 52/55 reads (95%) | called by muse, mutect2, varscan2
